Somatic mutation profile of tumor specimen C3L-00415-03 (aliquot CPT0010050006) from CPTAC case C3L-00415, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 64.6 years (23,586 days).
Specimen C3L-00415-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6839e70b-0042-4fd1-a42d-9c27ada7c68f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00415-31 (Blood Derived Normal), aliquot CPT0019860002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/474865ea-4d26-4840-bbc5-99dae00ae653

The open-access MAF lists 176 somatic variants for this specimen: 126 protein-altering or splice-affecting, 38 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 38, Nonsense Mutation 6, Frame Shift Del 6, Frame Shift Ins 4, 5'Flank 3, RNA 3, Splice Site 3, Intron 2, Splice Region 2, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNJ2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205820, CM136975, COSV99696396; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 92/382 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ADAM21 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs369445961; called by muse, mutect2, varscan2
- ATAD3A | c.219C>G p.D73E | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1278868758; called by muse, mutect2
- CFAP43 | c.2887G>T p.E963* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs752577989; called by mutect2, varscan2
- COL2A1 | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 54/450 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.171); catalogued as COSV61532084; called by muse, mutect2, varscan2
- DNAH17 | c.4819T>C p.S1607P | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1259598106; called by muse, mutect2
- DYNC1I1 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs755406657, COSV61455984, COSV61467899; called by muse, mutect2, varscan2
- EFCC1 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253548902, COSV71401930; called by muse, mutect2, varscan2
- FCRL2 | c.986C>A p.P329Q | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs146267875, COSV63834390; called by muse, mutect2, varscan2
- FMN2 | c.3841G>T p.G1281W | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV60415470; called by muse, mutect2, varscan2
- FOXL2 | c.273C>A p.Y91* | Nonsense Mutation (SNP) | VAF 174/777 reads (22%) | catalogued as CM077540, COSV100374924; called by muse, mutect2, varscan2
- FRMD7 | c.1262C>A p.P421H | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as CD065720; called by muse, mutect2, varscan2
- FRMPD4 | c.3505G>A p.A1169T | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs771597592, COSV66215660, COSV66217173; called by muse, mutect2, varscan2
- GALNTL6 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs1390582620, COSV72489150; called by muse, mutect2, varscan2
- GPSM1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1278475751, COSV61304618; called by muse, mutect2, varscan2
- HABP2 | c.285C>A p.F95L | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV63636760; called by muse, mutect2
- IFNL3 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV69830164; called by muse, mutect2, varscan2
- KCNH1 | c.1772G>T p.R591L (on ENST00000271751 / NM_172362.3; = p.R564L on NM_002238.4) | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657141; called by muse, varscan2
- KRTAP19-1 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 119/673 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.779); catalogued as COSV66861131; called by muse, mutect2, varscan2
- LOXHD1 | c.5248A>G p.M1750V (on ENST00000642948; = p.M639V on NM_001145472.3) | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs899369714; called by muse, mutect2, varscan2
- MLYCD | c.581T>A p.F194Y | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs556674494; called by muse, mutect2, varscan2
- MUC16 | c.36743G>A p.R12248H | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs75003158, COSV101202278; called by muse, mutect2, varscan2
- NDUFB11 | c.443A>G p.Q148R (on ENST00000377811 / NM_001135998.3; = p.Q158R on NM_019056.6) | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as COSV52101727; called by muse, mutect2, varscan2
- NTM | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66181952; called by muse, varscan2
- OCRL | c.1972G>A p.V658I | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs757516354, COSV100843646; called by muse, mutect2, varscan2
- OR13D1 | c.917T>C p.I306T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.381); catalogued as rs775483628; called by muse, mutect2, varscan2
- OR5L2 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1201959601, COSV65725305; called by muse, mutect2
- OTUD7A | c.1079G>A p.R360K (on ENST00000307050 / NM_001382637.1; = p.R353K on NM_130901.3) | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs778373603; called by muse, mutect2, varscan2
- PHF8 | c.2312C>T p.S771L (on ENST00000357988 / NM_001184896.1; = p.S735L on NM_015107.3) | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.758); catalogued as rs377130882, COSV57677953; called by muse, mutect2, varscan2
- PLCH1 | c.4948C>T p.R1650W (on ENST00000340059 / NM_001130960.2; = p.R1642W on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749296221, COSV58212112; called by muse, mutect2, varscan2
- PPP2R1A | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV59048414; called by muse, mutect2, varscan2
- PRRC2A | c.3716G>A p.R1239Q | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.389); catalogued as rs751127894; called by mutect2, varscan2
- RIMS2 | c.2566G>A p.D856N (on ENST00000666250 / NM_001348490.2; = p.D664N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51683172; called by muse, mutect2, varscan2
- SGMS2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs756549531; called by muse, mutect2, varscan2
- SLFN11 | c.2054A>G p.K685R | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV100390828; called by muse, mutect2, varscan2
- SPANXD | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 56/792 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs145377089, COSV100982246, COSV65152327; called by muse, mutect2
- TDRD3 | c.1883G>T p.G628V | Missense Mutation (SNP) | VAF 78/419 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1434261956, COSV52156492; called by muse, mutect2, varscan2
- TIE1 | c.2462G>A p.R821Q | Missense Mutation (SNP) | VAF 135/811 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759871396; called by muse, mutect2, varscan2
- TRABD | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 66/474 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs776456362, COSV57712525; called by muse, mutect2, varscan2
- WDCP | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs755167540, COSV54592612; called by muse, mutect2, varscan2
- XK | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 58/465 reads (12%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.697); catalogued as rs1556442152; called by muse, mutect2, varscan2
- ZIM3 | c.235C>A p.R79S | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.066); catalogued as COSV54142834; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2699C>T p.T900M | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs780230737, COSV100048158; called by muse, mutect2, varscan2
- AC127029.3 | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ACOT9 | c.548T>C p.M183T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- AKAP13 | c.1030G>T p.G344W | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ANKRD11 | c.5273C>T p.P1758L | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANO7 | c.305G>T p.G102V (on ENST00000274979; = p.G48V on NM_001001666.4) | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARAP2 | c.727del p.S243Pfs*10 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ATG16L2 | c.857A>T p.H286L | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- BARX1 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- BMPR1B | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2CD5 | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.471); called by muse, mutect2
- CAD | c.5160G>T p.E1720D | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CARMIL3 | c.2633A>G p.D878G | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CBWD1 | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CCDC158 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- CCK | c.262C>G p.P88A | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- CCNT2 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC7 | c.1675del p.T559Qfs*14 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- CFAP410 | c.143+1G>A p.X48_splice | Splice Site (SNP) | VAF 38/192 reads (20%) | called by muse, mutect2, varscan2
- CFAP58 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- CHD7 | c.2783A>T p.K928M | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CRYBB1 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 143/1015 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- DOCK11 | c.906C>A p.N302K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DPY19L2P1 | n.354G>A | Splice Region (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- FAM135B | c.1946G>T p.R649M | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- FAT2 | c.10211C>T p.P3404L | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2
- FBXL6 | c.838A>T p.T280S | Missense Mutation (SNP) | VAF 48/467 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FEZF2 | c.218T>C p.M73T | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FOXP3 | c.12del p.R5Gfs*57 | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | called by mutect2, pindel
- GLI3 | c.4345G>T p.G1449C | Missense Mutation (SNP) | VAF 243/1556 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- GRM1 | c.1028A>G p.Q343R | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.339); called by muse, mutect2
- HKDC1 | c.2129G>T p.G710V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- KMT2E | c.3381T>G p.D1127E | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KNDC1 | c.2988G>T p.L996= | Splice Region (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- KRCC1 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- LAS1L | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 49/375 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- MDGA2 | c.2122A>T p.T708S (on ENST00000399232 / NM_001113498.2; = p.T410S on NM_182830.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); called by muse, mutect2
- ME2 | c.1539C>G p.Y513* | Nonsense Mutation (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- MGAT4B | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- MGAT4B | c.731A>C p.K244T | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- MN1 | c.1877C>G p.A626G | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MTIF2 | c.1807del p.V603Lfs*8 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- MYO18B | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NAA16 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- NAGLU | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 40/530 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NLRP3 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 110/820 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOX4 | c.525C>G p.I175M | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2
- NUP160 | c.3589G>T p.A1197S | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.529); called by muse, mutect2
- OR2M5 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4C16 | c.91_92insA p.R31Qfs*10 | Frame Shift Ins (INS) | VAF 4/50 reads (8%) | called by mutect2, pindel
- OR7G3 | c.522del p.H176Tfs*6 | Frame Shift Del (DEL) | VAF 31/202 reads (15%) | called by mutect2, pindel, varscan2
- OTOG | c.6502C>A p.L2168M | Missense Mutation (SNP) | VAF 23/379 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2
- OTX2 | c.569C>A p.A190D (on ENST00000408990 / NM_172337.3; = p.A198D on NM_021728.4) | Missense Mutation (SNP) | VAF 79/595 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PHEX | c.2183A>G p.Q728R | Missense Mutation (SNP) | VAF 77/469 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHKA2 | c.344A>T p.K115M | Missense Mutation (SNP) | VAF 106/810 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLCB4 | c.2927A>C p.E976A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PLXNA3 | c.1829-2A>T p.X610_splice | Splice Site (SNP) | VAF 33/228 reads (14%) | called by muse, mutect2, varscan2
- PRICKLE3 | c.699T>A p.H233Q | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PRR27 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PTCHD1 | c.2226G>A p.M742I | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- QSER1 | c.3393G>T p.M1131I (on ENST00000399302; = p.M1260I on NM_001076786.3) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RGS3 | c.788dup p.R265Pfs*29 (on ENST00000350696 / NM_001282923.2; = p.R153Pfs*29 on NM_017790.4) | Frame Shift Ins (INS) | VAF 33/160 reads (21%) | called by mutect2, pindel, varscan2
- SH3YL1 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.881); called by muse, mutect2
- SLC14A1 | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 57/450 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- SLC25A24 | c.435_436insA p.E146Rfs*9 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- SLC35G1 | c.553T>G p.W185G (on ENST00000427197 / NM_001134658.3; = p.W184G on NM_153226.4) | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- SLC3A1 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPHKAP | c.1261A>T p.S421C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SUGP2 | c.3040C>A p.L1014M | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SUN2 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TET1 | c.1806C>A p.N602K | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- THEM5 | c.281A>G p.H94R | Missense Mutation (SNP) | VAF 92/476 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- TMEM132B | c.2599G>T p.D867Y | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TMEM201 | c.1052G>A p.W351* | Nonsense Mutation (SNP) | VAF 57/422 reads (14%) | called by muse, mutect2, varscan2
- TRDN | c.642_643del p.S214Rfs*5 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- VWF | c.3109-2A>T p.X1037_splice | Splice Site (SNP) | VAF 52/566 reads (9%) | called by muse, mutect2, varscan2
- WDFY3 | c.3110A>T p.H1037L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- XRN1 | c.3312T>A p.C1104* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- ZFPM1 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF358 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF592 | c.2414G>T p.G805V | Missense Mutation (SNP) | VAF 50/657 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZNF737 | c.1379A>G p.K460R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- ZNF880 | c.610_611insA p.V204Dfs*7 | Frame Shift Ins (INS) | VAF 3/22 reads (14%) | called by mutect2, pindel
- ASXL1 | c.27G>A p.K9= | Silent (SNP) | VAF 28/278 reads (10%) | called by muse, mutect2
- ATXN7L1 | c.2421C>T p.P807= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as rs1022312328; called by muse, varscan2
- CACNG6 | c.228C>T p.C76= | Silent (SNP) | VAF 10/276 reads (4%) | catalogued as rs1459324474, COSV53168622; called by muse, mutect2
- CELF5 | c.84G>A p.G28= | Silent (SNP) | VAF 50/297 reads (17%) | called by muse, mutect2, varscan2
- CSPG4 | c.4851C>T p.L1617= | Silent (SNP) | VAF 21/193 reads (11%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.1056C>G p.G352= | Silent (SNP) | VAF 66/406 reads (16%) | catalogued as COSV63583524; called by muse, mutect2, varscan2
- DSP | c.5970C>T p.T1990= | Silent (SNP) | VAF 8/208 reads (4%) | catalogued as rs992636849, COSV101131266, COSV65791474, COSV65796073; called by muse, mutect2
- ELMO3 | c.1023C>G p.L341= (on ENST00000652269; = p.L288= on NM_024712.5) | Silent (SNP) | VAF 53/325 reads (16%) | catalogued as COSV100681948; called by muse, mutect2, varscan2
- FILIP1L | c.2808A>T p.I936= (on ENST00000354552 / NM_182909.3; = p.I696= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- GALK2 | c.897G>A p.E299= | Silent (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
- GJA10 | c.363A>T p.P121= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- GLP1R | c.528G>A p.R176= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as rs866849283, COSV64714399; called by muse, varscan2
- H1-3 | c.261C>T p.S87= | Silent (SNP) | VAF 52/309 reads (17%) | catalogued as rs775041809, COSV55096681; called by muse, mutect2, varscan2
- HIGD2B | c.318C>A p.P106= | Silent (SNP) | VAF 33/140 reads (24%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.528C>A p.S176= | Silent (SNP) | VAF 145/990 reads (15%) | called by muse, mutect2, varscan2
- LDB3 | c.1893C>T p.T631= | Silent (SNP) | VAF 36/570 reads (6%) | called by muse, mutect2
- LMF2 | c.18C>T p.L6= | Silent (SNP) | VAF 84/584 reads (14%) | catalogued as rs1262430158; called by muse, mutect2, varscan2
- MAP7D3 | c.786T>G p.R262= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2
- MLYCD | c.582C>T p.F194= | Silent (SNP) | VAF 21/159 reads (13%) | catalogued as rs373343424; called by muse, mutect2, varscan2
- MYO10 | c.4518C>T p.T1506= | Silent (SNP) | VAF 21/304 reads (7%) | called by muse, mutect2
- NBAS | c.2811C>G p.P937= | Silent (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- NHSL2 | c.45G>T p.P15= | Silent (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- OXR1 | c.1278G>A p.Q426= (on ENST00000442977 / NM_001198532.1; = p.Q425= on NM_018002.3) | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- P2RY8 | c.735C>T p.A245= | Silent (SNP) | VAF 60/352 reads (17%) | catalogued as rs1219476667; called by muse, mutect2, varscan2
- POM121L2 | c.2571T>C p.I857= | Silent (SNP) | VAF 56/257 reads (22%) | called by muse, mutect2, varscan2
- PRKD2 | c.345C>T p.I115= | Silent (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
- RHBDF2 | c.2097C>T p.L699= | Silent (SNP) | VAF 35/639 reads (5%) | called by muse, mutect2
- SGIP1 | c.819T>C p.N273= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.1038T>C p.G346= | Silent (SNP) | VAF 54/337 reads (16%) | called by muse, mutect2, varscan2
- SIPA1 | c.1638T>A p.T546= | Silent (SNP) | VAF 53/320 reads (17%) | called by muse, mutect2, varscan2
- SKOR2 | c.1104G>T p.A368= | Silent (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- SOX11 | c.1146G>T p.G382= | Silent (SNP) | VAF 35/280 reads (13%) | catalogued as rs746249275; called by muse, mutect2, varscan2
- STK19 | c.297C>T p.S99= | Silent (SNP) | VAF 69/413 reads (17%) | called by muse, mutect2, varscan2
- TFAP2B | c.462G>C p.A154= | Silent (SNP) | VAF 52/545 reads (10%) | catalogued as COSV99540960; called by muse, mutect2
- TRIM64B | c.1182T>A p.P394= | Silent (SNP) | VAF 27/414 reads (7%) | called by muse, mutect2
- TSR1 | c.753C>T p.A251= | Silent (SNP) | VAF 54/230 reads (23%) | called by muse, mutect2, varscan2
- UBE2I | c.9G>A p.G3= | Silent (SNP) | VAF 48/326 reads (15%) | called by muse, mutect2, varscan2
- VNN2 | c.699G>A p.L233= | Silent (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
- AIG1 | c.399+22485C>T | Intron (SNP) | VAF 22/159 reads (14%) | catalogued as rs778000532; called by muse, mutect2, varscan2
- C5orf17 | n.422G>T | RNA (SNP) | VAF 14/105 reads (13%) | called by muse, mutect2, varscan2
- CDKL5 | c.*32C>A | 3'UTR (SNP) | VAF 103/625 reads (16%) | called by muse, mutect2, varscan2
- COG4 | chr16:70523556 G>T | 5'Flank (SNP) | VAF 50/370 reads (14%) | called by muse, mutect2, varscan2
- EYS | c.1767-6771G>T | Intron (SNP) | VAF 64/386 reads (17%) | called by muse, mutect2, varscan2
- LINC01591 | n.674A>T | RNA (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- MTMR8 | c.-33C>T | 5'UTR (SNP) | VAF 33/285 reads (12%) | called by muse, mutect2, varscan2
- PNO1 | chr2:68157796 C>A | 5'Flank (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- RNF32 | chr7:156640194 C>G | 5'Flank (SNP) | VAF 54/356 reads (15%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088454 C>A | 3'Flank (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25092187 G>T | 3'Flank (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- SSPOP | n.931A>G | RNA (SNP) | VAF 36/225 reads (16%) | catalogued as COSV50486688; called by muse, mutect2, varscan2
